Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3660, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3660-01A (Primary Tumor).

Diagnosis/ diagnoses:

Colon and rectosigmoid resection material show an ulcerated colon carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending to within 3.5 cm of a resection margin, probably the aboral resection margin, encircling the colon wall at a length of 6 cm. Invasive tumor spread tumor within all intestinal wall layers to the bordering mesocolic fatty tissue. The oral and aboral resection margin is tumor-free. Thirty-three mesocolic lymph nodes are tumor-free with uncharacteristic reactive lesions.

Tumor stage: pT3 pN0 (0/33) L0 V0; G2.

Source: NCI Genomic Data Commons file 988b0b4a-939a-4613-b71d-5313ea0afc8f (TCGA-AA-3660.5B62D771-4E67-4983-928F-B98FB1CAD99B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).